Somatic mutation profile of tumor specimen TCGA-PC-A5DN-01A (aliquot TCGA-PC-A5DN-01A-12D-A27P-09) from TCGA case TCGA-PC-A5DN, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 77.8 years (28,421 days).
Specimen TCGA-PC-A5DN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8a5992e-61cc-4332-92eb-2f6d5d4bd106.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PC-A5DN-10A (Blood Derived Normal), aliquot TCGA-PC-A5DN-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ab726c7-c721-4e9a-bd08-933641b44734

The open-access MAF lists 50 somatic variants for this specimen: 40 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, Nonsense Mutation 2, In Frame Ins 2, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.5891T>A p.L1964H | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99565286; called by muse, mutect2, varscan2
- ACSM2A | c.745A>G p.T249A (on ENST00000219054; = p.T170A on NM_001308169.2) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV54590811, COSV99524958; called by muse, mutect2, varscan2
- APOB | c.5168G>T p.S1723I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs570383610, COSV99264078; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPN | c.269A>C p.D90A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100978556; called by muse, mutect2, varscan2
- ATRX | c.5269G>C p.E1757Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100970203, COSV64878750; called by muse, varscan2
- CCDC60 | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 152/197 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554728; called by muse, mutect2, varscan2
- CCR1 | c.563C>G p.P188R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56121784, COSV99946658; called by muse, mutect2, varscan2
- CNR1 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV100759169; called by muse, mutect2, varscan2
- CPEB3 | c.1402G>C p.V468L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as rs773585852, COSV56459947, COSV99798789; called by muse, mutect2
- DOCK2 | c.3085T>A p.Y1029N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99910695; called by muse, mutect2, varscan2
- GCNA | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV101032425, COSV65466748; called by muse, mutect2, varscan2
- GUCA1A | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99273848; called by muse, mutect2
- HCK | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs761716878, COSV52944469; called by muse, mutect2, varscan2
- KLK3 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs148892721; called by muse, mutect2, varscan2
- MAGI3 | c.1540A>T p.I514F | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV100288289; called by muse, mutect2, varscan2
- NUAK1 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV54603969, COSV99776707; called by muse, mutect2
- OR2V2 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs147476494, COSV100080028; called by muse, mutect2, varscan2
- OR5M10 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV101595864; called by muse, mutect2
- OTOGL | c.1470C>A p.H490Q (on ENST00000547103; = p.H481Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101509036; called by muse, mutect2
- PLA2G4E | c.2119T>A p.S707T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101268534; called by muse, mutect2, varscan2
- PTH2R | c.411G>A p.K137= | Splice Region (SNP) | VAF 7/19 reads (37%) | catalogued as rs1268581591, COSV55918915; called by muse, mutect2, varscan2
- ROCK1 | c.2240A>G p.D747G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101296254; called by muse, mutect2, varscan2
- SCN11A | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181058; called by muse, mutect2, varscan2
- SH3RF2 | c.1246G>T p.G416C | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763090331, COSV100767627; called by muse, mutect2, varscan2
- SLCO4C1 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.143); catalogued as COSV100194618; called by muse, mutect2, varscan2
- STAT6 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.136); catalogued as COSV100273160; called by muse, mutect2
- SUSD1 | c.200_201insCCTC p.R68Lfs*7 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | catalogued as COSV100813192; called by mutect2, pindel, varscan2
- TBCE | c.424G>A p.V142I (on ENST00000366601; = p.V205I on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV64006454; called by muse, mutect2
- THSD7A | c.3406G>A p.G1136S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.401); catalogued as COSV101439728; called by muse, mutect2, varscan2
- TMEM168 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV100454524; called by muse, mutect2, varscan2
- TRPC1 | c.1486C>G p.L496V (on ENST00000476941 / NM_001251845.2; = p.L462V on NM_003304.4) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99858344; called by muse, mutect2, varscan2
- UNC13C | c.2804T>G p.L935* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99512811; called by muse, mutect2, varscan2
- WDFY3 | c.1493A>G p.D498G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99882396; called by muse, mutect2, varscan2
- ZFAND1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as rs1173671877, COSV55106673; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.801); catalogued as COSV100362834; called by muse, mutect2, varscan2
- ZNF77 | c.1292C>T p.T431I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100094340; called by muse, mutect2, varscan2
- AGTR1 | c.602_603del p.I201Tfs*26 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by pindel, varscan2
- FCGBP | c.11309T>C p.L3770P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- GATAD2A | c.66_68dup p.D23dup | In Frame Ins (INS) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- PLGRKT | c.146_148dup p.W49dup | In Frame Ins (INS) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- CDA | c.129C>T p.L43= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs149177918; called by muse, mutect2, varscan2
- CTSL | c.450G>A p.Q150= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs772325261, COSV100446621, COSV58246462; called by muse, mutect2, varscan2
- LRRTM4 | c.1236C>T p.G412= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs546452040, COSV69139553; called by muse, mutect2, varscan2
- MUC2 | c.2736G>T p.T912= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs551062642; called by muse, mutect2, varscan2
- PRG4 | c.2751C>T p.D917= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV100798120; called by muse, mutect2, varscan2
- RYR1 | c.2673C>T p.T891= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100614873; called by muse, mutect2, varscan2
- SMARCC1 | c.219C>A p.T73= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99592416; called by muse, mutect2
- SUPT20HL1 | c.1752A>T p.P584= | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- CCNP | c.514-79C>T | Intron (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99695784; called by muse, mutect2, varscan2
- SNORD116-2 | n.42G>C | RNA (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
